Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JQ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JQ-01A (Primary Tumor).

[page 1 of 4]
Requesting Doctor's Information:

HISTOPATHOLOGY FOR REVIEW

MACROSCOPIC:

Received were 19 slides, labelled:

MICROSCOPIC:

At the request of _____ the slides have been reviewed. I agree with the diagnosis of adrenal cortical carcinoma diagnosed by _____. The tumour is composed of variably pleomorphic cells, which are arranged in diffuse sheets, nests and cords. The cells have enlarged hyperchromatic nuclei. There are scattered cells with markedly atypical nuclei, including multi-nucleated forms. Occasional mitoses are present (up to 3/50 hpf). Atypical mitoses are not identified. The cells have variable amounts of eosinophilic granular cytoplasm. Cell borders are indistinct. There is a prominent myxoid stroma throughout the tumour. There are also prominent vessels. There is no capsular or venous space invasion, however sinusoidal invasion is seen in one area.

Immunohistochemistry was performed. The tumour cells are positive with calretinin and melin A. The tumour demonstrates four of the nine Weiss criteria, comprising high nuclear grade, loss of clear cells, diffuse architecture and sinusoidal invasion. In view of this, and the large size of the tumour, it is best regarded as an adrenal cortical carcinoma.

SUMMARY:

Right adrenal gland - Adrenal cortical carcinoma.

T-93010 M-83703

REPORTING PATHOLOGIST:

(Electronic Signature)

dx discrepancy from TSS states histology to be myxoid.

Criteria	W 1/8/13	Yes	No
Diagnosis Discrepancy	Myxoid		
HPA Discrepancy			

ATHOLOGY

ANATOMICAL PATHOLOGY

[page 2 of 4]
HISTOPATHOLOGY FOR REVIEW

Slides were reviewed at the request of _____ (treating surgeon). This review is part of a project examining comparative genomic hybridisation on adrenal tissue frozen at the time of surgery and involves centralised histopathological review including assignment of a Weiss score to a large number of adrenal tumours.

Pathological Diagnosis: Adrenal Cortical Carcinoma
Weight of Adrenal Gland: 148g

Weiss score with number of Weiss criteria present:4

High nuclear grade

Less than 25% Clear cells

Diffuse architecture

Sinusoidal invasion

Note: Many of the cells have oxyphilic cytoplasm imparting an oncocytoma like appearance

SUMMARY:

Adrenal Gland: Adrenal cortical carcinoma. Weiss score:4

T-93000 M-81400

REPORTING PATHOLOGIST:

(Electronic Signature)

COPIES	(5)
Page 1 of 1	

[page 3 of 4]
ADDITIONAL REPORT COPIES SENT TO

Requested: HISTOPATHOLOGY

R Adrenal

THIS TOP SECTION MAY BE DETACHED PRIOR TO FILING

Sex: F

HISTOPATHOLOGY REPORT

MACROSCOPIC:

"Right adrenal gland". The specimen consists of a previously opened, encapsulated oval tumour 148g and 85x55x70mm. The capsule is shiny and grey with a small amount of adherent adrenal gland and fat but the vast majority of the specimen is composed of tumour which has a variegated yellow to tan cut surface with prominent areas of haemorrhage. Representative sections. (Blocks A to L, with B including a tiny amount of attached adrenal gland) CAC4

MICROSCOPIC:

The adrenal cortex is replaced by a tumour composed of loosely cohesive cells with plentiful eosinophilic cytoplasm and round nuclei. There is considerable cellular pleomorphism with frequent large hyperchromatic nuclei. The cells are arranged in cords and sheets and in many places are separated by pools of mucinous material. In the more pleomorphic areas, there are up to three mitoses per ten high power fields. Many of the cells contain PAS positive globules. There is no evidence of capsular or vascular invasion. The tumour cells fail to stain for S100 protein, chromogranin A or calretinin. The appearance is in keeping with an adrenocortical carcinoma.

DIAGNOSIS: RIGHT ADRENAL GLAND - ADRENOCORTICAL CARCINOMA

Page 1 Continued Over

Criteria	
HPA Discrepancy	
Prior Pathology History	
Tumor/Syncytious Primary	
Case (circle)	QUALIFIED

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Usual	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Myxoid	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Myxoid features are seen in the top section we have. No way to know how abundant they are in the whole tumor.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge

vided by my institution is true and correct and has been quality controlled.

TSS Reviewer

Director

Date

I acknowledge that the information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the informed or is aware of the above discrepancy in diagnoses.

P.

re

Date /

Source: NCI Genomic Data Commons file fecbfb92-6c98-4091-936d-2a0884412dc7 (TCGA-OR-A5JQ.3AE0E638-5907-4B56-9C55-E58D97B27AFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).